Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EH, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EH-01A (Primary Tumor).

Date of surgery :

Left eye enucleation

Macroscopy

The eyeball measures 25 by 25 by 25 mm with a posterior segment of optic nerve of 8 mm. At the section of the eyeball there is a tumor of 12 by 10 mm. Samples have been made for cryopreservation and genomic profiling and the specimen has been then included entirely after fixation.

Microscopy

The tumor seen macroscopically correspond to a choroidal melanoma. The tumor cells are mostly non pigmented and fusiform. They are organized in crisscrossing bundles. There are atypical ovoid nuclei which show few mitotic figures with 1 mitosis

by 10 fields at the 400 magnification. The tumor is distant from the emergence of the optic nerve and distant from the ciliary processes. However it infiltrates the whole thickness of the sclera with extra sclera extension visible (specimen D and E). There are tumor cells around the extra scleral vessels without visible neoplastic embolus in the lymphatic channels.

Conclusion

Choroidal melanoma of the left eye

Predominant cell type fusiform

Size of the tumor: 12mm

Mitotic index is low

Whole sclera infiltration with extrasclerale extension

The optic nerve on its entire course as well as the meningeal sheaths are free

ICD-O-3
Melanoma, spindle cell NOS
8772/3
Site Choroid
C69.3
JW

Source: NCI Genomic Data Commons file 43f8dc74-d1fe-4726-a645-59143be3117a (TCGA-V4-A9EH.C0F9EB5A-8CBD-4BDB-A67C-B205AC198A42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).